Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A1OH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A1OH-01A (Primary Tumor).

[page 1 of 4]
3/9/11

pw

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:**A. LEFT TUBE AND OVARY, SALPINGO-OOPHORECTOMY:**

- Fallopian tube with focal tubal intraepithelial carcinoma (See synoptic report)
- Ovary with corpora albicantia and multifocal reactive lymphoid aggregates

B. RIGHT TUBE AND OVARY, SALPINGO-OOPHORECTOMY:

- Metastatic adenocarcinoma with lymphatic space invasion, high grade serous type, from endometrial primary
- Mullerian inclusion cysts
- Fallopian tube with tubal intraepithelial carcinoma involving fimbriated end

C. UTERUS WITH CERVIX, TOTAL HYSTERECTOMY:

- Cervix:
- Endocervical and ectocervical stroma diffusely involved by high grade serous adenocarcinoma
- Lymphatic space invasion present
- Endometrium:
- Uterine papillary serous carcinoma (UPSC) with diffuse involvement of endometrium with peripheral endometrial intraepithelial carcinoma
- Background atrophic changes
- Myometrium:
- Diffusely superficial and deep myoinvasion by high grade serous adenocarcinoma (full thickness involvement to serosa)
- Lymphatic space invasion present, extensive
- Monckeberg's vascular medial calcifications
- Serosa:
- Involved by high grade serous adenocarcinoma (full thickness involvement to serosa)
- Anterior inked margin positive

D. OMENTUM #1, OMENTECTOMY:

- Metastatic uterine papillary serous carcinoma
- Reactive mesothelial hyperplasia

E. OMENTUM #2, OMENTECTOMY:

- Metastatic uterine papillary serous carcinoma
- Reactive mesothelial hyperplasia

**SYNOPTIC REPORT:**

Applies To:

Patient Case(s):

Copy For:
Page 1 of 4

2011-03-09 10:00:00
2011-03-09 10:00:00

[page 2 of 4]
A : LEFT TUBE AND OVARY
B : RIGHT TUBE AND OVARY
C : UTERUS AND CERVIX
D : OMENTUM 1
E : OMENTUM 2

Macroscopic

Specimen Type:	Uterus Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
Other Organs Present:	None
Procedure:	Total abdominal hysterectomy and bilateral salpingo-oophorectomy
Specimen Integrity:	Intact hysterectomy specimen
Lymph Node Sampling:	No lymph nodes present

Microscopic

Histologic Type:	Serous adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Site:	Corpus Fundus Lower uterine segment Isthmus
Tumor Size:	Greatest dimension: 5.2cm Dimensions: 5.2 x 5 x 3cm
Myometrial Invasion:	Tumor extends through the entire uterine wall to serosal surface
Involvement of Cervix:	Invasion of cervical stromal connective tissue
Extent of Involvement of Other Organs:	Left ovary
Margins:	Tumor involves serosal aspect
Lymphovascular Invasion:	Present

Pathologic Staging (pTNM [FIGO]) AJCC 7th Edition 2010

Primary Tumor (pT):	pT3a [IIIA]: Tumor involves serosa and/or adnexa (direct extension or metastasis)
Regional Lymph Nodes (pN):	pNX: Cannot be assessed
Number of pelvic lymph nodes examined:	0
Number of pelvic lymph nodes involved:	0
Number of para-aortic lymph nodes examined:	0
Number of para-aortic lymph nodes involved:	0
Number of common iliac lymph nodes examined:	0
Number of common iliac lymph nodes involved:	0

[page 3 of 4]
lymph nodes involved:
Distant Metastasis (pM):

0
pM1 [IVB]: Distant metastasis
Site(s): Omentum

HISTORY:
Pre-op diagnosis: CA endometrial

MICROSCOPIC FINDINGS:
See diagnosis.

GROSS:

A. LT TUBE AND OVARY

Labeled with the patient's name, designated "lt tube and ovary", and received in formalin is an intact adnexa. The tortuous fallopian tube measures 4.0 cm in length and ranges from 0.4 cm in diameter to 0.9 cm in diameter. It has a fimbriated end. The overlying mesosalpinx is smooth and red-purple. Cut surface demonstrates a patent lumen lined with delicate pink-tan mucosa. The ovary measures 1.4 x 0.8 x 0.5 cm and has a smooth pink-yellow capsular surface. Cut surface demonstrates a single corpus albicans measuring 0.9 cm in greatest dimension. Representative sections are submitted.

- A1. Proximal and mid fallopian tube cross sections and entire fimbriated tip - multiple
- A2. Half of bisected ovary - 1
- A3. Additional tissue - multiple

B. RT TUBE AND OVARY

Labeled with the patient's name, designated "rt tube and ovary", and received in formalin is an intact adnexa. The tortuous fimbriated fallopian tube measures 5.5 cm in length and ranges from 0.3 to 0.5 cm in diameter. The overlying mesosalpinx is smooth pink-tan and unremarkable. The cut surface demonstrates a patent pinpoint lumen lined with delicate tan papilliferous mucosa. The attached ovary measures 1.8 x 0.7 x 0.5 cm. The capsular surface is pink and yellow. The cut surface demonstrates unremarkable ovarian parenchyma. Representative sections are submitted.

Slide key:

- B1. Proximal and mid fallopian tube cross sections and entire fimbriated tip - multiple
- B2. Entire bisected ovary - 2
- B3. Entirely submitted additional tissue - multiple

C. UTERUS WITH CERVIX

Labeled with the patient's name, designated "uterus and cervix", and received fresh for intraoperative consultation is a uterus and attached cervix. The uterus measures 7.3 cm in length, 5.1 cm cornu to cornu, and 5.0 cm anterior to posterior. The cervix measures 2.6 cm in length and 3.6 cm in maximum transverse dimensions. The ectocervix is pink to red and granular. Entirely filling the endometrial cavity is a large exophytic mass measuring 5.2 x 5.0 x 3.0 cm. The mass grossly extends into the cervix and is located approximately 1.0 cm from the os on the anterior side and 1.5 cm from the os on the posterior side. The serosa overlying the uterine corpus is smooth pink-red unremarkable. Approximately 50% of the mass has a friable red-brown necrotic cut surface. The muscular uterine wall ranges from 0.6 to 1.8 cm. The point of attachment of the mass is on the right wall. The mass invades to the serosal edge on the right side. The small amount of uninvolved myometrium is rubbery and pink-tan. The uninvolved endometrium is smooth and pink-tan. Representative sections are submitted.

Ink key:
Black - Anterior.
Blue - Posterior.

[page 4 of 4]
Red - Cervical end of lower uterine segment.

Slide key:

- C1. Anterior cervix - 1
- C2. Anterior lower uterine segment - 1
- C3. Posterior cervix - 1
- C4. Posterior lower uterine segment - 1
- C5-C8. Anterior myometrium with mass and serosa - 1 each
- C9, C10. Uninvolved endomyometrium with serosa to mass - 1 each
- C11, C12. Posterior myometrium with serosa and mass - 1 each

D. OMENTUM #1

Labeled with the patient's name, designated "omentum #1", and received in formalin is a fragment of finely lobulated yellow adipose tissue consistent with omentum measuring 7.6 x 6.0 x 1.0 cm. Masses are not identified. Representative sections are submitted.

D1. Multiple

E. OMENTUM #2

Labeled with the patient's name, designated "omentum #2", and received in formalin is a fragment of finely lobulated yellow adipose tissue consistent with omentum measuring 7.2 x 4.5 x 1.1 cm. Masses are not identified. Representative sections are submitted.

E1. Multiple

Gross dictated by:

INTRAOPERATIVE CONSULTATION:

C. UTERUS AND CERVIX, GROSS EXAMINATION:

- Bulky necrotic endometrial tumor with gross extrusion/involvement of cervix
- NOTE: Portion of tumor given for research purposes (TCGA)

A AND B. LEFT AND RIGHT ADNEXA, GROSS EXAMINATION:

- No gross tumor seen

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

NIHAA Discrepancy		/

(use pen or P₁)

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note that the use of immunohistochemical tests were developed and their performance characteristics determined by the manufacturer. If immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 5148ccc4-c05e-45ae-a355-43a04cc8fa68 (TCGA-A5-A1OH.AAF1B591-1A0D-48D2-BF59-95B0D605950A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).